Somatic mutation profile of cancer-model specimen HCM-BROD-0793-C15-85M (3D Organoid, passage 4; aliquot HCM-BROD-0793-C15-85M-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0793-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 55.2 years (20,179 days).
Specimen HCM-BROD-0793-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b93ca70-4867-4f17-b686-5b557c78d929.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0793-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0793-C15-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ef79a85-a868-4645-a3cb-6c8b32f640eb

The open-access MAF lists 168 somatic variants for this specimen: 107 protein-altering or splice-affecting, 54 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 54, Nonsense Mutation 8, Intron 4, In Frame Del 3, Frame Shift Del 3, 3'UTR 2, Splice Region 1, Nonstop Mutation 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 416/416 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMZ1 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 120/497 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs773580561; called by muse, mutect2, varscan2
- BCAT1 | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 170/1692 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753916893; called by muse, mutect2, varscan2
- BRINP1 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 137/421 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as rs375138030; called by muse, varscan2
- C1orf87 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 190/213 reads (89%) | catalogued as rs147997086, COSV64596556; called by muse, mutect2, varscan2
- CABIN1 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 283/346 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs567239001, COSV54077650; called by muse, mutect2, varscan2
- CCDC168 | c.10144dup p.R3382Kfs*19 | Frame Shift Ins (INS) | VAF 128/305 reads (42%) | catalogued as rs1183799771; called by mutect2, varscan2
- CHD4 | c.1676G>A p.R559Q (on ENST00000357008 / NM_001363606.2; = p.R572Q on NM_001273.5) | Missense Mutation (SNP) | VAF 179/452 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58904370; called by muse, mutect2, varscan2
- CYYR1 | c.382T>G p.L128V | Missense Mutation (SNP) | VAF 194/194 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54834792, COSV54835659; called by muse, mutect2, varscan2
- DCBLD2 | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 119/252 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58788754; called by mutect2, varscan2
- DIDO1 | c.3175G>A p.G1059R | Missense Mutation (SNP) | VAF 239/541 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99825780; called by muse, mutect2, varscan2
- DNAH9 | c.11335C>T p.R3779* | Nonsense Mutation (SNP) | VAF 40/430 reads (9%) | catalogued as rs779176965, COSV52379299; called by muse, mutect2
- EFCAB5 | c.356T>C p.F119S | Missense Mutation (SNP) | VAF 22/365 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as rs1456302203; called by muse, mutect2
- FSIP2 | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 157/159 reads (99%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100554351; called by muse, mutect2, varscan2
- FUT11 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 77/441 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1374390271; called by muse, mutect2, varscan2
- H3C2 | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 209/370 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.041); catalogued as COSV52520062; called by muse, mutect2, varscan2
- HK1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs747711080, COSV53859600; called by muse, mutect2, varscan2
- IL31RA | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 108/215 reads (50%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as rs921624282, COSV51683882; called by muse, mutect2, varscan2
- IPO8 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 388/551 reads (70%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs778254539, COSV56240309; called by muse, mutect2, varscan2
- JPH1 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 286/522 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs769389782; called by muse, mutect2, varscan2
- KLF15 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 132/491 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1281213893, COSV99955167; called by muse, mutect2, varscan2
- KRT33B | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 117/388 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs370317934; called by muse, mutect2, varscan2
- KRTAP26-1 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 190/190 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV62129072; called by muse, varscan2
- LRFN1 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 392/721 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1311724284, COSV50435653; called by muse, mutect2, varscan2
- LRRFIP2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 32/580 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs765165432, COSV104414724; called by muse, mutect2
- LVRN | c.1390del p.S464Lfs*15 | Frame Shift Del (DEL) | VAF 72/256 reads (28%) | catalogued as rs756702147; called by pindel, varscan2
- MMP8 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 140/376 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs563802778; called by muse, mutect2, varscan2
- MUC4 | c.4468C>T p.P1490S | Missense Mutation (SNP) | VAF 139/247 reads (56%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.65); catalogued as rs1233126201; called by muse, mutect2, varscan2
- NFKBID | c.580C>T p.Q194* (on ENST00000396901; = p.Q346* on NM_032721.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 34/509 reads (7%) | catalogued as COSV61728329; called by muse, mutect2
- NOP56 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs764465169; called by muse, mutect2, varscan2
- OR51D1 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 539/539 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1031260747; called by muse, mutect2, varscan2
- PCDHGC5 | c.2425C>T p.R809W | Missense Mutation (SNP) | VAF 125/875 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.2); catalogued as rs749918160, COSV52753161; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1005G>T p.R335S | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV62612337; called by muse, mutect2, varscan2
- POTEC | c.314G>T p.C105F | Missense Mutation (SNP) | VAF 185/553 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as rs879248532; called by muse, mutect2, varscan2
- PPP1R3A | c.1424A>C p.K475T | Missense Mutation (SNP) | VAF 148/150 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV52889490; called by muse, mutect2
- PRDX2 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 75/373 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs112697174, COSV56878298; called by muse, mutect2, varscan2
- PTPN18 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 24/534 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.161); catalogued as rs765171238; called by muse, mutect2
- RELL2 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 48/1092 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs146456008; called by muse, mutect2
- RGS18 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV66509185, COSV99054851; called by muse, mutect2, varscan2
- RTL1 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 139/412 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1361005947, COSV66017334; called by muse, mutect2, varscan2
- RTL5 | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 117/117 reads (100%) | catalogued as rs767497557; called by muse, mutect2, varscan2
- SHANK1 | c.3536C>T p.A1179V | Missense Mutation (SNP) | VAF 393/734 reads (54%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.862); catalogued as COSV99521896; called by muse, mutect2, varscan2
- SSRP1 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 51/656 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53480438; called by muse, mutect2
- STAG1 | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs753635471; called by muse, mutect2, varscan2
- STRC | c.3740C>T p.T1247I | Missense Mutation (SNP) | VAF 76/562 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1461173768; called by muse, varscan2
- STS | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs144731434; called by muse, mutect2, varscan2
- TFR2 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 456/799 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs751548369; called by muse, mutect2, varscan2
- TLR4 | c.659C>G p.P220R (on ENST00000355622 / NM_138554.5; = p.P180R on NM_003266.4) | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV62922649; called by muse, mutect2, varscan2
- TUBB8 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 209/392 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as rs559882106, COSV59115129; called by muse, mutect2, varscan2
- UBE3B | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 90/170 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs372352298; called by muse, mutect2, varscan2
- ZNF175 | c.1208A>C p.N403T | Missense Mutation (SNP) | VAF 265/482 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs756933793; called by muse, mutect2, varscan2
- ZNF28 | c.323A>G p.D108G | Missense Mutation (SNP) | VAF 264/506 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs781145103; called by muse, mutect2, varscan2
- ZNF43 | c.1250A>G p.K417R | Missense Mutation (SNP) | VAF 212/319 reads (66%) | SIFT tolerated (0.27); PolyPhen benign (0.261); catalogued as COSV61684309; called by muse, mutect2, varscan2
- ACOX1 | c.124A>T p.N42Y | Missense Mutation (SNP) | VAF 73/307 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- ACSM3 | c.1528A>G p.S510G | Missense Mutation (SNP) | VAF 21/411 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- C6orf132 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 56/300 reads (19%) | called by mutect2, varscan2
- CCDC50 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 105/291 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP221 | c.1802C>G p.P601R | Missense Mutation (SNP) | VAF 70/455 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CTNND2 | c.1123C>A p.H375N | Missense Mutation (SNP) | VAF 336/519 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DCHS2 | n.235T>G | Splice Region (SNP) | VAF 110/127 reads (87%) | called by muse, mutect2, varscan2
- DCP1B | c.1280C>G p.S427C | Missense Mutation (SNP) | VAF 138/567 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKQ | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 317/351 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EPHX4 | c.548C>G p.P183R | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2
- ERBB4 | c.2209T>C p.W737R | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EXOSC4 | c.738A>T p.*246Cext*9 | Nonstop Mutation (SNP) | VAF 200/357 reads (56%) | called by muse, mutect2, varscan2
- FAM47C | c.497_501del p.E166Afs*6 | Frame Shift Del (DEL) | VAF 30/202 reads (15%) | called by mutect2, pindel, varscan2
- FOXG1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 227/644 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- FZD6 | c.1637C>G p.P546R | Missense Mutation (SNP) | VAF 182/444 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GABBR1 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 52/536 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.813); called by muse, mutect2
- GBF1 | c.425C>G p.T142S | Missense Mutation (SNP) | VAF 114/183 reads (62%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- GLIS3 | c.2176C>T p.H726Y | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GTF3C3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 34/577 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.257); called by muse, mutect2
- HEATR1 | c.1040_1054del p.L347_L351del | In Frame Del (DEL) | VAF 43/160 reads (27%) | called by mutect2, pindel, varscan2
- HOMER2 | c.967A>G p.K323E (on ENST00000304231 / NM_199330.3; = p.K312E on NM_004839.4) | Missense Mutation (SNP) | VAF 244/502 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HOXD11 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.399); called by mutect2, varscan2
- HPSE2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 171/290 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- IRF2BP1 | c.679A>C p.K227Q | Missense Mutation (SNP) | VAF 375/860 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MAPK9 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 50/472 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NOMO1 | c.3475G>C p.G1159R | Missense Mutation (SNP) | VAF 96/1012 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOVA1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 103/403 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OLFM3 | c.224A>C p.N75T (on ENST00000338858 / NM_001288821.1; = p.N55T on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 245/356 reads (69%) | SIFT tolerated (0.42); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- OR2M4 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 80/374 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ORC5 | c.924C>G p.F308L | Missense Mutation (SNP) | VAF 58/364 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PHIP | c.3625A>T p.I1209F | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- PITHD1 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- POT1 | c.968_970del p.L323del | In Frame Del (DEL) | VAF 78/80 reads (98%) | called by mutect2, pindel, varscan2
- POTEC | c.1295A>G p.N432S | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PPP2R3A | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PWWP2A | c.668A>T p.N223I | Missense Mutation (SNP) | VAF 88/761 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by mutect2, varscan2
- RNF169 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 42/1592 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2
- RORA | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 44/572 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2
- RPP40 | c.271T>A p.S91T | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- SHISA7 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 38/663 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- SIN3B | c.3126G>A p.W1042* | Nonsense Mutation (SNP) | VAF 181/673 reads (27%) | called by muse, mutect2, varscan2
- SLC6A1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- SLIT3 | c.3198_3219del p.Y1066* | Frame Shift Del (DEL) | VAF 92/787 reads (12%) | called by mutect2, pindel
- TCF15 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 152/672 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TENM2 | c.257T>A p.I86N | Missense Mutation (SNP) | VAF 282/354 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- TNXB | c.5770C>T p.L1924F (on ENST00000647633; = p.L1677F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/491 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13B | c.9559G>A p.G3187S | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- WBP2NL | c.709_712delinsA p.G237_Y238delinsN | In Frame Del (DEL) | VAF 229/241 reads (95%) | called by pindel, varscan2*
- WDR47 | c.2698G>T p.D900Y (on ENST00000369962 / NM_001142551.2; = p.D901Y on NM_014969.5) | Missense Mutation (SNP) | VAF 122/470 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ZFP36L2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 44/803 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2
- ZFP82 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 265/600 reads (44%) | called by muse, mutect2, varscan2
- ZNF329 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 101/498 reads (20%) | called by muse, mutect2, varscan2
- ZNF510 | c.1490T>C p.F497S | Missense Mutation (SNP) | VAF 225/389 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF550 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 301/585 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGO1 | c.2517C>T p.A839= | Silent (SNP) | VAF 57/714 reads (8%) | called by muse, mutect2
- ANKRD17 | c.291C>A p.G97= | Silent (SNP) | VAF 418/470 reads (89%) | called by mutect2, varscan2
- APP | c.2229C>A p.T743= | Silent (SNP) | VAF 23/211 reads (11%) | called by muse, mutect2, varscan2
- CEP128 | c.1779C>T p.S593= | Silent (SNP) | VAF 207/336 reads (62%) | catalogued as rs139506469; called by muse, mutect2, varscan2
- CHGB | c.93A>T p.G31= | Silent (SNP) | VAF 156/343 reads (45%) | called by muse, mutect2, varscan2
- CLC | c.351G>A p.K117= | Silent (SNP) | VAF 27/404 reads (7%) | called by muse, mutect2
- CLEC18B | c.172C>T p.L58= | Silent (SNP) | VAF 4/7 reads (57%) | called by mutect2, varscan2
- CNTNAP5 | c.939A>T p.P313= | Silent (SNP) | VAF 103/243 reads (42%) | catalogued as rs1255174102; called by muse, mutect2, varscan2
- DNAJA4 | c.627C>T p.I209= (on ENST00000343789; = p.I238= on NM_018602.3) | Silent (SNP) | VAF 70/312 reads (22%) | catalogued as rs750983168; called by muse, mutect2, varscan2
- DSP | c.4989C>T p.A1663= | Silent (SNP) | VAF 232/393 reads (59%) | called by muse, mutect2, varscan2
- ELFN1 | c.150C>T p.P50= | Silent (SNP) | VAF 354/746 reads (47%) | catalogued as rs757471650; called by muse, mutect2, varscan2
- F13A1 | c.1695G>T p.P565= | Silent (SNP) | VAF 260/532 reads (49%) | called by muse, mutect2
- FBXO42 | c.870C>G p.V290= | Silent (SNP) | VAF 75/560 reads (13%) | catalogued as rs552728510; called by muse, mutect2, varscan2
- FCGR2A | c.207G>A p.E69= (on ENST00000271450 / NM_001136219.3; = p.E68= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 338/342 reads (99%) | catalogued as rs1487882177; called by muse, mutect2
- FREM1 | c.6286A>C p.R2096= | Silent (SNP) | VAF 52/146 reads (36%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.1941G>A p.A647= | Silent (SNP) | VAF 348/638 reads (55%) | catalogued as rs1460236557; called by mutect2, varscan2
- HDAC4 | c.930C>T p.V310= | Silent (SNP) | VAF 103/781 reads (13%) | called by muse, mutect2, varscan2
- HSPA1L | c.279T>C p.P93= | Silent (SNP) | VAF 74/752 reads (10%) | called by muse, mutect2
- IRF2 | c.594C>T p.D198= | Silent (SNP) | VAF 112/150 reads (75%) | called by muse, mutect2, varscan2
- KCTD8 | c.249C>T p.A83= | Silent (SNP) | VAF 38/298 reads (13%) | called by muse, varscan2
- KIF17 | c.762C>T p.G254= | Silent (SNP) | VAF 141/688 reads (20%) | catalogued as rs770464662; called by muse, mutect2, varscan2
- KIF26A | c.315C>T p.L105= | Silent (SNP) | VAF 34/564 reads (6%) | catalogued as rs780500407; called by muse, mutect2
- KIN | c.681G>A p.P227= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs369856846; called by muse, mutect2, varscan2
- L3MBTL3 | c.132A>G p.E44= | Silent (SNP) | VAF 122/318 reads (38%) | called by muse, mutect2, varscan2
- LBR | c.36A>G p.V12= | Silent (SNP) | VAF 25/310 reads (8%) | catalogued as rs760209707, COSV99687358; called by muse, mutect2
- LETM2 | c.429C>T p.D143= (on ENST00000379957 / NM_001286819.2; = p.D96= on NM_144652.3) | Silent (SNP) | VAF 71/264 reads (27%) | catalogued as rs369104625; called by muse, mutect2, varscan2
- LRP2 | c.10992G>A p.S3664= | Silent (SNP) | VAF 79/241 reads (33%) | catalogued as rs562394755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAGEL2 | c.1878C>T p.I626= | Silent (SNP) | VAF 36/628 reads (6%) | called by muse, mutect2
- MASP2 | c.1143A>T p.T381= | Silent (SNP) | VAF 296/539 reads (55%) | called by muse, mutect2, varscan2
- MAT1A | c.1182A>C p.V394= | Silent (SNP) | VAF 62/217 reads (29%) | called by muse, mutect2, varscan2
- MICAL2 | c.687G>T p.L229= | Silent (SNP) | VAF 26/503 reads (5%) | called by muse, mutect2
- MICAL2 | c.1179G>A p.V393= | Silent (SNP) | VAF 344/344 reads (100%) | called by muse, varscan2
- MLNR | c.18C>T p.N6= | Silent (SNP) | VAF 50/467 reads (11%) | catalogued as rs550929994; called by muse, mutect2, varscan2
- MLXIPL | c.468G>A p.A156= | Silent (SNP) | VAF 198/623 reads (32%) | catalogued as rs1554598716; called by muse, mutect2, varscan2
- MYCT1 | c.660G>A p.P220= | Silent (SNP) | VAF 119/338 reads (35%) | catalogued as rs773532214; called by muse, varscan2
- NLRP14 | c.1779G>A p.A593= | Silent (SNP) | VAF 47/568 reads (8%) | catalogued as rs368365867; called by muse, mutect2
- NOTCH1 | c.3261C>T p.S1087= | Silent (SNP) | VAF 394/597 reads (66%) | catalogued as rs543586029; called by muse, mutect2, varscan2
- NUTM2G | c.1590C>T p.V530= | Silent (SNP) | VAF 284/990 reads (29%) | called by muse, mutect2, varscan2
- OR10A2 | c.453C>T p.F151= | Silent (SNP) | VAF 44/638 reads (7%) | catalogued as rs1473595599, COSV56299079; called by muse, mutect2
- PABPC1L | c.45G>A p.V15= | Silent (SNP) | VAF 260/567 reads (46%) | catalogued as rs1371060902; called by muse, mutect2, varscan2
- PARG | c.2871C>T p.Y957= | Silent (SNP) | VAF 20/311 reads (6%) | called by muse, mutect2
- PCDHA11 | c.2160G>C p.L720= | Silent (SNP) | VAF 185/1034 reads (18%) | called by muse, mutect2, varscan2
- RANBP2 | c.4932A>G p.T1644= | Silent (SNP) | VAF 38/391 reads (10%) | called by muse, mutect2, varscan2
- SEMA6A | c.1206G>T p.V402= | Silent (SNP) | VAF 99/287 reads (34%) | called by muse, mutect2, varscan2
- SHROOM2 | c.2457C>T p.H819= | Silent (SNP) | VAF 55/264 reads (21%) | catalogued as rs1430388211, COSV66607978; called by muse, mutect2, varscan2
- SLC4A1AP | c.1104G>A p.K368= | Silent (SNP) | VAF 45/497 reads (9%) | called by muse, mutect2
- SNRK | c.759T>C p.D253= | Silent (SNP) | VAF 85/187 reads (45%) | called by muse, mutect2, varscan2
- SPDYE6 | c.807C>T p.I269= | Silent (SNP) | VAF 288/1929 reads (15%) | called by muse, mutect2, varscan2
- TMCC2 | c.786C>T p.A262= | Silent (SNP) | VAF 37/742 reads (5%) | catalogued as rs769302375; called by muse, mutect2
- TPO | c.165C>T p.Y55= | Silent (SNP) | VAF 192/430 reads (45%) | catalogued as rs149346954, CM1510459, COSV61101360; ClinVar: likely benign; called by muse, varscan2
- TRBV2 | c.15C>T p.L5= | Silent (SNP) | VAF 69/320 reads (22%) | catalogued as rs776577517; called by muse, mutect2, varscan2
- ZNF234 | c.1116C>T p.Y372= | Silent (SNP) | VAF 272/547 reads (50%) | catalogued as rs766123560, COSV70602772; called by muse, mutect2, varscan2
- ZNF439 | c.1143G>A p.P381= | Silent (SNP) | VAF 22/352 reads (6%) | catalogued as rs201064778, COSV58309103; called by muse, mutect2
- ZNF445 | c.711G>A p.K237= | Silent (SNP) | VAF 51/296 reads (17%) | called by muse, mutect2, varscan2
- AGAP1 | c.164-38205_164-38198del | Intron (DEL) | VAF 154/517 reads (30%) | called by mutect2, pindel, varscan2
- COL6A5 | c.*344G>A | 3'UTR (SNP) | VAF 148/272 reads (54%) | catalogued as COSV55205626; called by muse, mutect2, varscan2
- ENPP2 | c.973-2114C>T | Intron (SNP) | VAF 196/455 reads (43%) | catalogued as rs540074619, COSV50014744; called by muse, mutect2, varscan2
- SPEF2 | c.4448-3087G>T | Intron (SNP) | VAF 873/1021 reads (86%) | called by muse, mutect2, varscan2
- ZCCHC24 | c.*130G>A | 3'UTR (SNP) | VAF 136/398 reads (34%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1245T>C | Intron (SNP) | VAF 102/289 reads (35%) | called by muse, mutect2, varscan2
- ZNF772 | chr19:57467042 T>C | 3'Flank (SNP) | VAF 36/617 reads (6%) | called by muse, mutect2
